Gene-level copy-number profile of tumor specimen TCGA-GN-A265-06A from TCGA case TCGA-GN-A265, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.0 years (19,712 days).
Specimen TCGA-GN-A265-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ba4e343e-00ba-456e-9a80-7815134aabb3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A265-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a65bc013-40e9-4dc0-9870-ee7523a72fb8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 13,743; copy number 2: 34,181; copy number 3: 9,590; copy number 4: 2,040; copy number 5: 111; copy number 7: 10; copy number 8: 2; copy number 12: 27; copy number 13: 11; copy number 18: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A265-06A-21D-A191-01): tumor purity 0.17, ploidy 2.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 13 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr15:73,255,334–75,121,666, 72 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 166 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,564,106–71,754,229, 16 genes, copy number 13–18 (within-gene range 2–18): AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1.
- chr3:85,799,987–85,828,050, 1 gene, copy number 12: CADM2-AS2.
- chr9:14,475–1,057,552, 26 genes, copy number 12: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2.
- chr15:65,726,054–66,685,794, 29 genes, copy number 5 (within-gene range 2–5): RAB11A, AC011939.2, AC011939.1, HNRNPA1P44, U6, MEGF11, MIR4311, AC055855.2, DIS3L, AC055855.1, TIPIN, SCARNA14, Y_RNA, RPL9P25, MAP2K1, ATP5MFP6, RPL35AP32, AC116913.1, SNAPC5, MIR4512, RPL4, SNORD18C, AC116913.2, SNORD18B, SNORD16, SNORD18A, ZWILCH, LCTL, LINC01169.
- chr15:76,736,641–78,383,155, 46 genes, copy number 5: RN7SKP217, RCN2, RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1, AC046168.1, AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1, CSPG4P13, AC104758.2, AC104758.3, RN7SL214P, COMMD4P1, AC104758.4, ADAMTS7P3, TBC1D2B, AC104758.1, SH2D7, SNORA63, CIB2, IDH3A, AC090260.1, ACSBG1, AC090607.3, DNAJA4, WDR61, AC090607.4, AC090607.2, AC090607.1, AC090607.5, AC011270.2, CRABP1, AC011270.1.
- chr15:85,178,628–85,330,334, 8 genes, copy number 7: AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3.
- chr15:85,380,596–85,389,884, 2 genes, copy number 7: MIR7706, RNU7-79P.
- chr15:86,079,973–87,029,052, 1 gene, copy number 8 (within-gene range 1–8): AGBL1.
- chr15:86,630,266–86,631,136, 1 gene, copy number 8: AC012229.1.
- chr22:34,017,422–36,093,352, 36 genes, copy number 5: LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2.

Autosomal genes at a single copy (total copy number 1): 11,329. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
